Somatic mutation profile of tumor specimen TCGA-F4-6461-01A (aliquot TCGA-F4-6461-01A-11D-1771-10) from TCGA case TCGA-F4-6461, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 41.5 years (15,151 days).
Specimen TCGA-F4-6461-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b87dcc4-d4bf-474c-8b8a-adf9cde206e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6461-10A (Blood Derived Normal), aliquot TCGA-F4-6461-10A-01D-1806-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e538354-72a6-4d20-ab25-a8d97182b5da

The open-access MAF lists 151 somatic variants for this specimen: 114 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 34, Nonsense Mutation 7, Splice Site 4, Splice Region 2, Frame Shift Ins 1, 3'UTR 1, Frame Shift Del 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2828C>A p.S943* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | catalogued as rs1554084512, CM021064, CM086470, COSV57334177, COSV57340756, COSV57390748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 22/101 reads (22%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 35/111 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 49/106 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 83/293 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 76/248 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALPP | c.657+1G>A p.X219_splice | Splice Site (SNP) | VAF 29/84 reads (35%) | catalogued as rs1206646601, COSV67398422; called by muse, mutect2, varscan2
- ANKAR | c.3700+2T>C p.X1234_splice | Splice Site (SNP) | VAF 36/100 reads (36%) | catalogued as COSV55619165; called by muse, mutect2, varscan2
- ASB15 | c.476T>C p.M159T | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs762910488, COSV51929888; called by muse, mutect2, varscan2
- ATF1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1036461202, COSV50396278; called by muse, mutect2, varscan2
- BCOR | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.83); PolyPhen probably damaging (1); catalogued as COSV60720609; called by muse, mutect2, varscan2
- BRWD3 | c.2418T>A p.N806K | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.028); catalogued as COSV100955876, COSV64749231; called by muse, mutect2, varscan2
- CD200R1 | c.836C>A p.S279Y (on ENST00000471858 / NM_170780.3; = p.S302Y on NM_138806.4) | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV55602109, COSV55604724; called by muse, mutect2, varscan2
- CDC73 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs748952219, COSV66470933; called by muse, mutect2, varscan2
- CHPF2 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs374488900; called by mutect2, varscan2
- CILP | c.2058G>T p.Q686H | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV99974066; called by muse, mutect2, varscan2
- CLIC3 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV65406922; called by muse, mutect2, varscan2
- CORO6 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372681638; called by muse, mutect2, varscan2
- CUX1 | c.2563G>A p.G855S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs144907719; called by muse, mutect2, varscan2
- CYP4Z1 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 149/557 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV61967051; called by muse, mutect2, varscan2
- CYS1 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.247); catalogued as rs780173331, COSV100007622, COSV59940275; called by muse, mutect2, varscan2
- DCAF4L2 | c.143A>G p.E48G | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60483342; called by muse, mutect2, varscan2
- DDX20 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63831249, COSV63831769; called by muse, mutect2, varscan2
- DEFB124 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1411014894, COSV58343772; called by muse, mutect2, varscan2
- DNAH8 | c.5395G>T p.V1799L | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV59485835; called by muse, mutect2, varscan2
- DOT1L | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs752264656, COSV67110438; called by muse, varscan2
- DTD1 | c.85G>C p.V29L | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV66282711; called by muse, mutect2, varscan2
- DUSP22 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs144879804; called by muse, mutect2, varscan2
- ELF3 | c.688+1dup | Frame Shift Ins (INS) | VAF 13/73 reads (18%) | catalogued as COSV100668861; called by mutect2, pindel
- FAM47C | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368685662, COSV63723449, COSV63725914; called by muse, mutect2, varscan2
- FBL | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs149587207; called by muse, mutect2, varscan2
- FBN3 | c.1633G>A p.V545M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs142269916; called by muse, mutect2, varscan2
- FBXO24 | c.436G>A p.V146I (on ENST00000241071 / NM_033506.3; = p.V184I on NM_012172.5) | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs768479204, COSV53827670; called by muse, mutect2, varscan2
- FOXG1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV57399122; called by muse, mutect2, varscan2
- FSHR | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58628033; called by muse, mutect2
- GPR182 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs368453485; called by muse, mutect2, varscan2
- GRIA1 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587776937, CM1211454, COSV53598273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIK2 | c.1913G>A p.G638D | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59715149; called by muse, mutect2, varscan2
- GSTA4 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63956125; called by muse, mutect2, varscan2
- H2BC11 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as rs978774690, COSV60362993; called by muse, mutect2, varscan2
- HNRNPF | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV61562418; called by muse, mutect2, varscan2
- HYDIN | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV55501866; called by muse, mutect2, varscan2
- IKBKE | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781909564, COSV65625725; called by muse, mutect2, varscan2
- JADE1 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.107); catalogued as COSV56909986; called by muse, mutect2, varscan2
- KANSL1 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV52267578; called by muse, mutect2, varscan2
- KIF12 | c.1241C>T p.A414V (on ENST00000640217; = p.A276V on NM_138424.1) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.236); catalogued as COSV65117962; called by muse, mutect2, varscan2
- KIZ | c.405G>A p.K135= | Splice Region (SNP) | VAF 45/135 reads (33%) | catalogued as rs1366906494, COSV99852487; called by muse, mutect2, varscan2
- KRT3 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.014); catalogued as COSV58817647; called by muse, mutect2, varscan2
- KRT6B | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV52887067; called by muse, mutect2, varscan2
- L3MBTL3 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs769544082, COSV62390054; called by muse, mutect2, varscan2
- LDLRAD3 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV59690142; called by muse, mutect2, varscan2
- LRRC56 | c.424-1G>T p.X142_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as COSV54248544; called by muse, mutect2, varscan2
- MED28 | c.306A>T p.L102F | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52847561; called by muse, mutect2, varscan2
- MUC16 | c.41105G>A p.G13702E | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.997); catalogued as COSV66697457; called by muse, varscan2
- MYO5B | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV53222835, COSV53233563; called by muse, mutect2, varscan2
- MYO9A | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs865917027, COSV61859709; called by muse, mutect2, varscan2
- N4BP2L2 | c.1429A>G p.N477D | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57230543; called by muse, mutect2, varscan2
- NAF1 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99919451; called by muse, varscan2
- NFIL3 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as rs773631235, COSV52684939; called by muse, mutect2, varscan2
- NKAPL | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777565461, COSV59199641; called by muse, mutect2, varscan2
- NLRP13 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV100738653; called by muse, mutect2, varscan2
- NOX4 | c.1025A>G p.H342R | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs1474336435, COSV54466861; called by muse, mutect2
- NRK | c.4531C>T p.R1511* | Nonsense Mutation (SNP) | VAF 31/133 reads (23%) | catalogued as rs1246400734, COSV54608954; called by muse, mutect2, varscan2
- NUGGC | c.936C>A p.C312* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as rs535493146, COSV100429156, COSV58440041; called by muse, mutect2, varscan2
- OBSCN | c.9546G>A p.A3182= | Splice Region (SNP) | VAF 11/51 reads (22%) | catalogued as rs753370298, COSV52841276; called by muse, mutect2, varscan2
- OR13D1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs182904893; called by muse, mutect2, varscan2
- PCDHA2 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1300605850, COSV65366143; called by muse, mutect2, varscan2
- PCDHA6 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65342498; called by muse, mutect2, varscan2
- PDIA5 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.072); catalogued as COSV60253159; called by muse, mutect2, varscan2
- PDILT | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1373532778, COSV56703412; called by muse, mutect2, varscan2
- PLAGL2 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.227); catalogued as rs760161049, COSV99867676; called by muse, mutect2, varscan2
- PNMA8A | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs774965879, COSV58139636; called by muse, mutect2, varscan2
- POLR3B | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57285348; called by muse, mutect2
- PRKCSH | c.1519A>C p.M507L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99372048; called by muse, mutect2, varscan2
- PTH2R | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs747468776, COSV55914670; called by muse, mutect2, varscan2
- PTPN13 | c.6616G>T p.G2206C (on ENST00000411767 / NM_080683.3; = p.G2187C on NM_006264.3) | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57408093, COSV57419138; called by muse, mutect2, varscan2
- RASA1 | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV56926559; called by muse, mutect2, varscan2
- REV3L | c.5140T>A p.S1714T | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV62622491, COSV62624382; called by muse, mutect2, varscan2
- RNF220 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764633164, COSV62405141; called by muse, mutect2, varscan2
- SAGE1 | c.2627T>G p.V876G | Missense Mutation (SNP) | VAF 105/388 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.581); catalogued as COSV61019019; called by muse, mutect2, varscan2
- SASH3 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs1374058569, COSV63556850; called by muse, mutect2, varscan2
- SCML1 | c.151A>G p.T51A (on ENST00000380041 / NM_001037540.3; = p.T24A on NM_006746.6) | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.899); catalogued as rs184140147, COSV66241088; called by muse, mutect2, varscan2
- SIGLEC7 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs140841032, COSV58317452; called by muse, mutect2, varscan2
- SKIV2L | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs763973489, COSV64814742; called by muse, mutect2, varscan2
- SLC12A1 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369307402, COSV101118323; called by mutect2, varscan2
- SLC25A31 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs753666991, COSV55422336; called by muse, mutect2, varscan2
- SPTA1 | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV63761129; called by muse, mutect2, varscan2
- TAS2R43 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs774865839, COSV67863470; called by muse, mutect2, varscan2
- TENM1 | c.1168+1G>A p.X390_splice | Splice Site (SNP) | VAF 66/200 reads (33%) | catalogued as COSV64441209, COSV64446377; called by muse, mutect2, varscan2
- TEX37 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.068); catalogued as rs1558632071, COSV57557151; called by muse, mutect2, varscan2
- TLR7 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as rs748655746, COSV66123662; called by muse, mutect2, varscan2
- TRAM2 | c.950A>G p.H317R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99480465; called by muse, mutect2
- TRO | c.2642G>C p.S881T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV51509017; called by muse, mutect2, varscan2
- TRPS1 | c.1592G>A p.R531Q (on ENST00000220888 / NM_001330599.2; = p.R544Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs769392409, COSV55266120; called by muse, mutect2, varscan2
- TWNK | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | catalogued as COSV52970774; called by muse, mutect2, varscan2
- UBE2U | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 111/375 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV64281120, COSV64281912; called by muse, mutect2, varscan2
- UBIAD1 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65148328; called by muse, mutect2, varscan2
- USH2A | c.13641G>T p.E4547D | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.949); catalogued as COSV100229205, COSV56370849; called by muse, mutect2, varscan2
- USP44 | c.520A>T p.K174* | Nonsense Mutation (SNP) | VAF 36/132 reads (27%) | catalogued as COSV51567844; called by muse, mutect2, varscan2
- ZAN | c.6458G>A p.C2153Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1159903537, COSV61816109; called by muse, mutect2, varscan2
- ZAP70 | c.650A>T p.K217M | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99386058; called by muse, mutect2, varscan2
- ZDHHC24 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.139); catalogued as rs752192038, COSV100130757; called by muse, mutect2, varscan2
- ZNF100 | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs773362638, COSV59750648; called by muse, mutect2, varscan2
- ZNF100 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs746401806, COSV59750657; called by mutect2, varscan2
- ZNF16 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as rs867116174, COSV99429974; called by muse, mutect2, varscan2
- ZNF275 | c.299A>G p.H100R | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV64705580; called by muse, mutect2, varscan2
- ZNF304 | c.1960G>T p.A654S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.043); catalogued as COSV56586808; called by muse, mutect2, varscan2
- ZNF423 | c.2002C>T p.R668W (on ENST00000563137 / NM_001379286.1; = p.R660W on NM_015069.4) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs779555962, COSV52190514; called by muse, mutect2, varscan2
- ZNF595 | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV100227964; called by muse, mutect2, varscan2
- ZYX | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1186726196, COSV51970540; called by muse, mutect2, varscan2
- CWC25 | c.34T>C p.W12R | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXD4L4 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASGRP1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); called by muse, mutect2
- REPS1 | c.1556_1557del p.F519Yfs*3 (on ENST00000450536 / NM_001286611.2; = p.F518Yfs*3 on NM_031922.4) | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- ACOT1 | c.801C>T p.Y267= | Silent (SNP) | VAF 20/245 reads (8%) | catalogued as COSV100233468; called by muse, mutect2
- ALMS1 | c.105G>A p.A35= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV52510079; called by muse, mutect2, varscan2
- AP2A2 | c.912G>A p.A304= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs368727985; called by muse, mutect2, varscan2
- C4orf50 | c.390G>A p.L130= (on ENST00000324058; = p.L1362= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- CIBAR1 | c.171G>A p.A57= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs755482814, COSV100844755; called by muse, mutect2, varscan2
- COMMD10 | c.606A>G p.T202= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as rs994549834, COSV57241938; called by muse, mutect2, varscan2
- DMKN | c.78C>T p.S26= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs754296680, COSV100304034; called by muse, mutect2
- DPYD | c.771C>T p.C257= | Silent (SNP) | VAF 56/162 reads (35%) | catalogued as rs754745863, COSV64594846; called by muse, mutect2, varscan2
- ELAPOR2 | c.2322A>G p.L774= (on ENST00000450689 / NM_001142749.3; = p.L607= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV51892804; called by muse, mutect2, varscan2
- GCNT3 | c.21C>T p.L7= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as rs767379702, COSV68532651; called by muse, mutect2, varscan2
- GNAS | c.969C>A p.V323= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100008026; called by muse, mutect2, varscan2
- IGSF22 | c.1305C>T p.R435= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs779678523, COSV60039487; called by muse, mutect2, varscan2
- INSRR | c.3303C>T p.D1101= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs746766711, COSV63872595; called by muse, mutect2, varscan2
- ITGB7 | c.2193C>T p.C731= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs370893853; called by muse, mutect2, varscan2
- KIAA0100 | c.5604C>T p.N1868= | Silent (SNP) | VAF 41/168 reads (24%) | catalogued as COSV101197445; called by muse, mutect2, varscan2
- KL | c.1830G>A p.Q610= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs188551232; called by muse, mutect2, varscan2
- MLLT6 | c.330C>T p.Y110= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs780174315; called by muse, mutect2, varscan2
- OR51Q1 | c.378G>A p.V126= | Silent (SNP) | VAF 62/216 reads (29%) | catalogued as COSV56180830; called by muse, mutect2, varscan2
- P2RY14 | c.678G>A p.S226= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs529815467, COSV56400719; called by muse, mutect2, varscan2
- PCDHGA3 | c.561G>A p.E187= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs112672535, COSV53933646; called by muse, mutect2, varscan2
- PDCL2 | c.318T>C p.N106= | Silent (SNP) | VAF 105/370 reads (28%) | catalogued as COSV55263487; called by muse, mutect2, varscan2
- PIM2 | c.33G>A p.A11= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs375934218, COSV50238322, COSV99331561; called by muse, mutect2, varscan2
- PLB1 | c.2196C>A p.A732= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV59837546; called by muse, mutect2, varscan2
- PRAMEF14 | c.438C>A p.P146= | Silent (SNP) | VAF 57/162 reads (35%) | called by muse, mutect2, varscan2
- RBMXL2 | c.220C>T p.L74= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV60981044; called by muse, mutect2, varscan2
- RNF168 | c.630G>A p.K210= | Silent (SNP) | VAF 56/198 reads (28%) | catalogued as COSV58839827; called by muse, mutect2, varscan2
- TAZ | c.747C>A p.L249= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV54797609; called by muse, mutect2, varscan2
- TIMP2 | c.624G>A p.A208= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs778309949, COSV99431081; called by mutect2, varscan2
- TRAK1 | c.1842G>A p.T614= (on ENST00000327628 / NM_001349247.2; = p.T556= on NM_014965.5) | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs748144263, COSV58261640; called by muse, mutect2, varscan2
- TTC21B | c.1875C>T p.D625= | Silent (SNP) | VAF 116/440 reads (26%) | catalogued as rs201527373, COSV54636252; called by muse, mutect2, varscan2
- TTC30B | c.537C>T p.A179= | Silent (SNP) | VAF 39/141 reads (28%) | catalogued as rs1452969019, COSV68809870; called by muse, mutect2, varscan2
- TTN | c.98010A>C p.S32670= (on ENST00000591111; = p.S25246= on NM_003319.4) | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV60402881; called by muse, mutect2, varscan2
- TULP4 | c.1347C>T p.D449= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs779943537, COSV65572197; called by muse, mutect2, varscan2
- ZNF646 | c.3753C>T p.I1251= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV54927035; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156942 C>T | 3'Flank (SNP) | VAF 26/74 reads (35%) | catalogued as rs769526533; called by muse, mutect2, varscan2
- NACA | c.71-3643C>G | Intron (SNP) | VAF 19/49 reads (39%) | catalogued as rs1173783686, COSV100771763; called by muse, mutect2, varscan2
- XIRP2 | c.*881C>T | 3'UTR (SNP) | VAF 25/89 reads (28%) | catalogued as COSV54739915; called by muse, mutect2, varscan2
